Somatic mutation profile of tumor specimen MP2PRT-PAUTUD-TBP1-A (aliquot MP2PRT-PAUTUD-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUTUD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (765 days).
Specimen MP2PRT-PAUTUD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27f75514-e7a0-44ac-9508-24bc953b1cc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTUD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTUD-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e947c4ce-bd95-4ac1-af4e-8ff0935e39e2

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 167/612 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- PTPN11 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 133/346 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C17orf50 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 228/815 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.399); catalogued as rs1555602123; called by muse, mutect2, varscan2
- USP43 | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 207/652 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758991416, COSV53300157; called by muse, mutect2, varscan2
- PFKP | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 163/543 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- B3GALT5 | c.651C>T p.T217= | Silent (SNP) | VAF 143/722 reads (20%) | catalogued as rs560831388; called by muse, mutect2, varscan2
- DLG2 | c.2040C>A p.T680= | Silent (SNP) | VAF 127/289 reads (44%) | catalogued as rs996507713; called by muse, mutect2, varscan2
- SKAP1 | c.480C>T p.Y160= | Silent (SNP) | VAF 124/482 reads (26%) | catalogued as rs768485885; called by muse, mutect2, varscan2
